Surgical pathology report (de-identified scan), TCGA case TCGA-4G-AAZG, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Sapienza University of Rome, specimen TCGA-4G-AAZG-01A (Primary Tumor).

pathology report

Date of tumor procurement:

Anatomic site: intrahepatic

Histology diagnosis: moderately differentiated intrahepatic cholangiocarcinoma

Immunohistochemistry: CK7 positive, CK20 and TTF1 negative

Histological examination:

Left liver: resected parenchyma of 17x10x4.7 cm containing a whitish nodule of 5 cm, located 5.5 cm distant from the resection margin. Histologically it is a moderately differentiated adenocarcinoma with an immunohistochemical profile consistent with intrahepatic cholangiocarcinoma with positivity for cytokeratin 7 and negative for cytokeratin 20 and TTF1. The liver tissue shows mild steatosis (40%) associated with chronic inflammation and fibrosis of mild to moderate (grade 2/6 fibrosis, Ishak).

Reactive lymphadenitis in hepatic lymph node and in 7 celiac lymph nodes.

ICD O 3
Cholangiocarcinoma 8160/3
Site: Intrahepatic bile duct
C22.1
QD 4/22/14

Source: NCI Genomic Data Commons file 68701d44-1590-40a6-ba3b-319c53c95c22 (TCGA-4G-AAZG.4E32E573-17EA-49A4-A90F-A0830E3279C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).